Somatic mutation profile of tumor specimen TARGET-10-PAPAVR-09A (aliquot TARGET-10-PAPAVR-09A-01D) from TARGET case TARGET-10-PAPAVR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,312 days).
Specimen TARGET-10-PAPAVR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24b11d9f-84c3-404a-9432-661731136437.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPAVR-10A (Blood Derived Normal), aliquot TARGET-10-PAPAVR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cab02383-d9ca-44bc-b585-413166938bdf

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 4, Silent 2, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 24/50 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRL4 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.173); catalogued as COSV66064483; called by muse, mutect2, varscan2
- CHRM1 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs1007009594, COSV61006154; called by muse, mutect2
- FAT1 | c.5347G>A p.V1783M | Missense Mutation (SNP) | VAF 62/218 reads (28%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as rs572509773; called by muse, varscan2
- HPSE2 | c.1774C>T p.R592* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as rs369345201, COSV100984618; called by muse, mutect2, varscan2
- IRF2 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs754089440, COSV66930277; called by muse, mutect2, varscan2
- NOS2 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as rs148070104, COSV58223419; called by muse, mutect2, varscan2
- RDH16 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs748725495; called by muse, mutect2, varscan2
- SOX7 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV58730713; called by muse, mutect2, varscan2
- STXBP5 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs201466855; called by muse, mutect2, varscan2
- TRAJ47 | c.2T>A p.*1= | Missense Mutation (SNP) | VAF 28/36 reads (78%) | catalogued as rs1357947792; called by muse, mutect2, varscan2
- DOP1A | c.4632T>G p.S1544R | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- CDK5RAP2 | c.3894C>T p.F1298= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs373113031; called by muse, mutect2, varscan2
- USP45 | c.1272T>G p.P424= | Silent (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- FRMD4A | c.760-80G>A | Intron (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- PAX3 | chr2:222201055 G>A | 3'Flank (SNP) | VAF 19/44 reads (43%) | catalogued as rs536679300; called by muse, varscan2
- SCN3A | c.4537-111G>A | Intron (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- SLC15A4 | c.842+505G>C | Intron (SNP) | VAF 12/86 reads (14%) | catalogued as rs111991699; called by muse, varscan2
- YIF1A | c.427+124A>C | Intron (SNP) | VAF 42/134 reads (31%) | called by muse, mutect2, varscan2
